Somatic mutation profile of cancer-model specimen HCM-BROD-0721-C43-85M (Adherent Cell Line, passage 4; aliquot HCM-BROD-0721-C43-85M-01D-A83U-36), derived from the metastatic tumor of HCMI case HCM-BROD-0721-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 57.7 years (21,082 days).
Specimen HCM-BROD-0721-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34c50974-42bb-433a-9dd1-3136c94f8a28.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0721-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0721-C43-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8605913e-7443-4bae-acf9-a4cc326964da

The open-access MAF lists 455 somatic variants for this specimen: 315 protein-altering or splice-affecting, 128 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 282, Silent 128, Nonsense Mutation 24, Intron 6, 3'UTR 4, Frame Shift Del 3, Splice Site 2, Splice Region 2, RNA 1, In Frame Del 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRB1 | c.2833G>A p.G945R | Missense Mutation (SNP) | VAF 185/267 reads (69%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs749746650, COSV66331163; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.8326C>T p.R2776* | Nonsense Mutation (SNP) | VAF 236/461 reads (51%) | catalogued as rs137854466, CM940772, COSV57312804; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 176/425 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 263/399 reads (66%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 254/254 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587780071, CM120848, COSV52677226, COSV52796536, COSV53623808; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.6943C>T p.Q2315* | Nonsense Mutation (SNP) | VAF 39/132 reads (30%) | catalogued as COSV101447279; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3497dup p.N1166Kfs*26 | Frame Shift Ins (INS) | VAF 93/561 reads (17%) | catalogued as rs1567281568; called by mutect2, pindel, varscan2
- ADGRV1 | c.8978C>T p.S2993F | Missense Mutation (SNP) | VAF 237/237 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV67980466; called by muse, mutect2, varscan2
- ADH1B | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs1353041149, COSV59298672; called by muse, mutect2, varscan2
- ADH6 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 157/273 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs1394964764; called by muse, mutect2, varscan2
- AIPL1 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 355/355 reads (100%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); catalogued as COSV51507710; called by muse, mutect2, varscan2
- AMIGO1 | c.1148G>A p.S383N | Missense Mutation (SNP) | VAF 160/473 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1329228013, COSV100881059; called by muse, mutect2, varscan2
- ANKRD33 | c.649G>A p.V217M (on ENST00000340970 / NM_001304459.2; = p.V342M on NM_182608.4) | Missense Mutation (SNP) | VAF 529/529 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771237309, COSV56604895; called by muse, mutect2, varscan2
- APOB | c.7846G>A p.D2616N | Missense Mutation (SNP) | VAF 219/455 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); catalogued as COSV51929847, COSV51954808; called by muse, mutect2, varscan2
- ASPM | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 12/270 reads (4%) | catalogued as COSV54134733; called by muse, mutect2
- BDKRB1 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 282/576 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as rs1464615714, COSV99387937; called by muse, mutect2, varscan2
- BMPER | c.1537G>A p.G513R | Missense Mutation (SNP) | VAF 297/620 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51818222; called by muse, mutect2, varscan2
- BRWD3 | c.3358C>T p.P1120S | Missense Mutation (SNP) | VAF 197/197 reads (100%) | SIFT tolerated (0.26); PolyPhen benign (0.109); catalogued as rs1277496917; called by muse, mutect2, varscan2
- C19orf71 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 305/619 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs368547478; called by muse, mutect2, varscan2
- C9 | c.1165C>G p.L389V | Missense Mutation (SNP) | VAF 116/116 reads (100%) | SIFT tolerated (0.36); PolyPhen benign (0.062); catalogued as rs781415536; called by muse, mutect2, varscan2
- C9orf50 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 141/226 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758796621; called by muse, mutect2, varscan2
- CALCR | c.1300G>A p.G434R (on ENST00000649521 / NM_001164737.2; = p.G418R on NM_001742.4) | Missense Mutation (SNP) | VAF 289/641 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as rs1448985676, COSV100810396, COSV100810660; called by muse, mutect2, varscan2
- CALCR | c.1299G>A p.W433* (on ENST00000649521 / NM_001164737.2; = p.W417* on NM_001742.4) | Nonsense Mutation (SNP) | VAF 288/640 reads (45%) | catalogued as COSV100810844, COSV64012245; called by muse, mutect2, varscan2
- CFTR | c.2935G>A p.D979N | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV50042546; called by muse, mutect2, varscan2
- CKM | c.350G>A p.G117D | Missense Mutation (SNP) | VAF 292/628 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as rs1219871446, COSV55531888, COSV99675478; called by muse, mutect2, varscan2
- CNTNAP2 | c.2256G>A p.W752* | Nonsense Mutation (SNP) | VAF 169/344 reads (49%) | catalogued as COSV62148128; called by muse, mutect2, varscan2
- COL17A1 | c.2780G>C p.G927A | Missense Mutation (SNP) | VAF 112/272 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as rs750876156; called by muse, varscan2
- COL21A1 | c.1712C>T p.P571L | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1276418403; called by muse, mutect2, varscan2
- COL4A3 | c.1984G>A p.G662R | Missense Mutation (SNP) | VAF 192/480 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM161088, COSV101170291; called by muse, mutect2, varscan2
- COL4A4 | c.2604G>A p.M868I | Missense Mutation (SNP) | VAF 327/766 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.212); catalogued as COSV61630422; called by muse, mutect2, varscan2
- COL4A4 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 143/335 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV61635475; called by muse, mutect2, varscan2
- CPZ | c.1843G>A p.E615K (on ENST00000360986 / NM_001014447.3; = p.E604K on NM_003652.3) | Missense Mutation (SNP) | VAF 411/676 reads (61%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs775874480, COSV59923215; called by muse, mutect2, varscan2
- CSAD | c.713C>T p.P238L (on ENST00000444623 / NM_001244705.2; = p.P265L on NM_015989.5) | Missense Mutation (SNP) | VAF 236/236 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1248041143, COSV57245666; called by muse, mutect2, varscan2
- CSF1R | c.592G>A p.V198I | Missense Mutation (SNP) | VAF 219/219 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as COSV99640571; called by muse, mutect2, varscan2
- CTCF | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 270/595 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50533050; called by muse, mutect2, varscan2
- DARS2 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 80/299 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1196303255, COSV53408370; called by muse, mutect2, varscan2
- DCDC1 | c.2803C>T p.P935S (on ENST00000597505 / NM_001367979.1; = p.P42S on NM_020869.3) | Missense Mutation (SNP) | VAF 135/365 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as COSV100338011, COSV60303277; called by muse, mutect2, varscan2
- EYA1 | c.344C>T p.T115I | Missense Mutation (SNP) | VAF 213/840 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as rs1368387497; called by muse, mutect2, varscan2
- FAM181A | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 349/692 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs370661001; called by muse, mutect2, varscan2
- FAT1 | c.8437C>T p.P2813S | Missense Mutation (SNP) | VAF 241/417 reads (58%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.948); catalogued as COSV101499488; called by muse, mutect2, varscan2
- FES | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 250/730 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs779391057; called by muse, varscan2
- FGB | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 92/252 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774502903; called by muse, mutect2, varscan2
- FGL2 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 263/501 reads (52%) | SIFT tolerated (0.78); PolyPhen benign (0.083); catalogued as rs150654104, COSV50382184; called by muse, mutect2, varscan2
- FNDC1 | c.4292G>A p.G1431E | Missense Mutation (SNP) | VAF 312/609 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51943734; called by muse, mutect2, varscan2
- FSCN1 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 580/1184 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.816); catalogued as rs1254960652; called by muse, mutect2, varscan2
- FUT2 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 369/741 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs201026795, COSV101218146; called by muse, mutect2, varscan2
- GAL3ST3 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 439/779 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV100360876; called by muse, mutect2, varscan2
- GCM2 | c.1406C>T p.S469F | Missense Mutation (SNP) | VAF 209/409 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV65275893; called by muse, mutect2, varscan2
- GHITM | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 158/329 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100930107; called by muse, mutect2, varscan2
- GRIA1 | c.2116C>T p.R706* | Nonsense Mutation (SNP) | VAF 207/207 reads (100%) | catalogued as COSV53625087; called by muse, mutect2, varscan2
- GRM3 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 340/689 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV64471421; called by muse, mutect2, varscan2
- IGHG4 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 319/1083 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.208); catalogued as rs1389090917; called by muse, mutect2, varscan2
- IL22RA1 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 246/435 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as COSV54628920, COSV54629670; called by muse, mutect2
- INAVA | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 241/392 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1013509036, COSV66257787; called by muse, mutect2, varscan2
- ITGA4 | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 104/235 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs563896829, COSV67899391; called by muse, mutect2, varscan2
- KCNB2 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 673/988 reads (68%) | SIFT tolerated (0.07); PolyPhen benign (0.195); catalogued as COSV73048821; called by muse, mutect2, varscan2
- KCND2 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 197/461 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58577018; called by muse, mutect2, varscan2
- KCNH8 | c.2938C>T p.P980S | Missense Mutation (SNP) | VAF 269/560 reads (48%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs1013848471, COSV60461253; called by muse, mutect2, varscan2
- KCNK18 | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 227/439 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.093); catalogued as COSV57970906; called by muse, mutect2, varscan2
- KCNQ3 | c.1021G>A p.V341I | Missense Mutation (SNP) | VAF 432/645 reads (67%) | SIFT tolerated (0.62); PolyPhen benign (0.068); catalogued as rs764957038, COSV66465131; called by muse, mutect2, varscan2
- KRT5 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 407/407 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as rs1312675397; called by muse, mutect2, varscan2
- LGALS4 | c.22G>A p.G8S | Missense Mutation (SNP) | VAF 385/825 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV55488993; called by muse, mutect2, varscan2
- LHCGR | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 249/527 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54297692; called by muse, mutect2, varscan2
- LILRA1 | c.802C>T p.L268F | Missense Mutation (SNP) | VAF 241/605 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs771309246, COSV99252006; called by muse, varscan2
- LIPF | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 118/266 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as COSV53283163; called by muse, mutect2, varscan2
- LRP1B | c.8714C>T p.P2905L | Missense Mutation (SNP) | VAF 186/418 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.265); catalogued as COSV67225728; called by muse, mutect2, varscan2
- LRRC17 | c.326G>A p.S109N | Missense Mutation (SNP) | VAF 238/462 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV50868491; called by muse, varscan2
- LURAP1 | c.216C>G p.I72M | Missense Mutation (SNP) | VAF 86/324 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); catalogued as COSV100915138; called by muse, mutect2, varscan2
- MARCHF4 | c.421A>T p.K141* | Nonsense Mutation (SNP) | VAF 364/749 reads (49%) | catalogued as COSV56105900; called by muse, mutect2, varscan2
- MCTP1 | c.1627G>A p.G543R | Missense Mutation (SNP) | VAF 154/154 reads (100%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.998); catalogued as COSV100386100; called by muse, mutect2, varscan2
- MEGF8 | c.186G>A p.E62= | Splice Region (SNP) | VAF 318/690 reads (46%) | catalogued as rs1196128416; called by muse, mutect2, varscan2
- MEIS2 | c.799G>A p.D267N (on ENST00000561208 / NM_170675.5; = p.D254N on NM_002399.3) | Missense Mutation (SNP) | VAF 238/384 reads (62%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.449); catalogued as COSV54937494; called by muse, varscan2
- MGAT4A | c.1469G>A p.G490E | Missense Mutation (SNP) | VAF 147/314 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV53848934; called by muse, mutect2, varscan2
- MOCOS | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 234/234 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754636835, COSV99733827; called by muse, mutect2, varscan2
- MUC16 | c.19910C>T p.S6637F | Missense Mutation (SNP) | VAF 256/553 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as COSV67484243; called by muse, mutect2, varscan2
- MUC16 | c.3149G>A p.G1050E | Missense Mutation (SNP) | VAF 284/571 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as rs866645734, COSV101200463; called by muse, mutect2, varscan2
- MUC17 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 261/578 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.19); catalogued as rs866365154, COSV100071942; called by muse, mutect2
- MYO7A | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 187/493 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.085); catalogued as rs782227657; called by muse, mutect2, varscan2
- NCKAP5 | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 140/349 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100491473; called by muse, mutect2, varscan2
- NCR1 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 115/1416 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.812); catalogued as COSV52557917; called by muse, mutect2
- NDRG4 | c.248G>A p.G83E (on ENST00000570248 / NM_001378344.1; = p.G115E on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 240/489 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs770266993; called by muse, mutect2, varscan2
- NPAS4 | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 452/782 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.316); catalogued as rs768389587, COSV60650585; called by muse, mutect2, varscan2
- NPAS4 | c.2209G>A p.G737R | Missense Mutation (SNP) | VAF 218/539 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV60650075; called by muse, mutect2, varscan2
- NUTM1 | c.2953C>T p.P985S | Missense Mutation (SNP) | VAF 142/405 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs531635527; called by muse, mutect2, varscan2
- OFD1 | c.2498A>G p.N833S | Missense Mutation (SNP) | VAF 223/223 reads (100%) | SIFT tolerated (0.37); PolyPhen benign (0.019); catalogued as rs781184750; called by muse, mutect2, varscan2
- OR13C3 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 278/440 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.165); catalogued as rs375714407; called by muse, mutect2, varscan2
- OR2V1 | c.838A>G p.T280A | Missense Mutation (SNP) | VAF 201/202 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs758950381; called by muse, mutect2, varscan2
- OR8D4 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.144); catalogued as COSV104394537, COSV58429456; called by muse, mutect2
- OR8K5 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 137/346 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.038); catalogued as COSV100537175; called by muse, mutect2, varscan2
- PADI6 | c.1356G>A p.M452I | Missense Mutation (SNP) | VAF 197/298 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs762954758; called by muse, mutect2, varscan2
- PCDHA6 | c.1291G>A p.G431S | Missense Mutation (SNP) | VAF 243/250 reads (97%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101129560; called by muse, mutect2, varscan2
- PCLO | c.11491C>T p.R3831C | Missense Mutation (SNP) | VAF 291/600 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61626253; called by muse, mutect2, varscan2
- PHRF1 | c.3649C>T p.P1217S (on ENST00000264555 / NM_001286581.2; = p.P1216S on NM_020901.4) | Missense Mutation (SNP) | VAF 547/964 reads (57%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs745774046; called by muse, mutect2, varscan2
- PIGS | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 255/256 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs756533381, COSV99257277; called by muse, mutect2, varscan2
- PIK3C2G | c.4133C>T p.S1378F (on ENST00000676171; = p.S1337F on NM_004570.5) | Missense Mutation (SNP) | VAF 79/298 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV56817213; called by muse, mutect2, varscan2
- PITPNM3 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 187/187 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs754290443, COSV52601149, COSV99338193; called by muse, mutect2, varscan2
- PKHD1L1 | c.4637A>G p.N1546S | Missense Mutation (SNP) | VAF 503/748 reads (67%) | SIFT tolerated (0.36); PolyPhen benign (0.075); catalogued as COSV104428476; called by muse, mutect2, varscan2
- PLEC | c.3761C>T p.A1254V (on ENST00000322810 / NM_201380.4; = p.A1144V on NM_000445.5) | Missense Mutation (SNP) | VAF 402/1531 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV59698711; called by muse, mutect2, varscan2
- PLXNB2 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 544/1081 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100834191; called by muse, mutect2, varscan2
- PNMA8B | c.451C>A p.L151I | Missense Mutation (SNP) | VAF 344/760 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.16); catalogued as COSV66536383; called by muse, mutect2, varscan2
- PRB2 | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 204/873 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.593); catalogued as COSV66983280; called by muse, mutect2, varscan2
- PROS1 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 109/235 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs373983977, CM064172, COSV67777518; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- QSOX1 | c.1721G>A p.R574Q | Missense Mutation (SNP) | VAF 413/637 reads (65%) | SIFT tolerated (0.36); PolyPhen benign (0.211); catalogued as rs750160362; called by muse, mutect2, varscan2
- RAB40C | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 203/479 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50194419; called by muse, mutect2, varscan2
- RAG1 | c.274C>T p.H92Y | Missense Mutation (SNP) | VAF 209/533 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV55026767, COSV55027754; called by muse, mutect2, varscan2
- RASD2 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 409/878 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.42); catalogued as rs1427977197; called by muse, mutect2, varscan2
- RGPD4 | c.1759-1G>T p.X587_splice | Splice Site (SNP) | VAF 66/178 reads (37%) | catalogued as COSV61750639; called by muse, mutect2, varscan2
- RHOH | c.469C>T p.R157W | Missense Mutation (SNP) | VAF 389/614 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769924998, COSV67804715; called by muse, mutect2, varscan2
- RLBP1 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 214/598 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.062); catalogued as rs1567123991; called by muse, mutect2, varscan2
- RNF180 | c.1058C>T p.S353F | Missense Mutation (SNP) | VAF 263/263 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs150368490; called by muse, mutect2, varscan2
- RORC | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 189/624 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as rs199550478, COSV59092062; called by muse, mutect2, varscan2
- RP1 | c.3017A>G p.K1006R | Missense Mutation (SNP) | VAF 203/669 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV73139165; called by muse, mutect2, varscan2
- RUNX1 | c.1316T>A p.M439K (on ENST00000344691 / NM_001001890.3; = p.M466K on NM_001754.5) | Missense Mutation (SNP) | VAF 470/938 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99038615; called by mutect2, varscan2
- SARDH | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 134/437 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376813433, COSV100898804; called by muse, mutect2
- SCAF4 | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 193/382 reads (51%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.311); catalogued as COSV54584567; called by muse, mutect2, varscan2
- SCML4 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 152/352 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as rs866343046; called by muse, mutect2, varscan2
- SEMA3E | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 227/479 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as COSV57083673; called by muse, mutect2, varscan2
- SERPINB10 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 200/200 reads (100%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs200550911; called by muse, mutect2, varscan2
- SERPING1 | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 186/476 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.116); catalogued as rs757566838; called by muse, mutect2, varscan2
- SLC17A4 | c.1288G>A p.G430R | Missense Mutation (SNP) | VAF 83/208 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55079345, COSV99765759; called by muse, mutect2, varscan2
- SLC22A24 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 167/319 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV70302859; called by muse, mutect2, varscan2
- SLC8A1 | c.201A>C p.Q67H | Missense Mutation (SNP) | VAF 251/569 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV60480453; called by muse, mutect2, varscan2
- SLC9A2 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 146/369 reads (40%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.701); catalogued as COSV52135951; called by muse, mutect2, varscan2
- SMG7 | c.2951C>T p.T984I | Missense Mutation (SNP) | VAF 306/428 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as rs1279458099; called by muse, mutect2, varscan2
- STON1 | c.1733G>A p.W578* | Nonsense Mutation (SNP) | VAF 211/473 reads (45%) | catalogued as rs865851204; called by muse, mutect2, varscan2
- STRBP | c.1868C>T p.A623V | Missense Mutation (SNP) | VAF 33/320 reads (10%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.062); catalogued as rs750032338, COSV62118881; called by muse, mutect2
- SYNE1 | c.3038G>A p.G1013E (on ENST00000367255 / NM_182961.4; = p.G1020E on NM_033071.3) | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV55123603; called by muse, mutect2, varscan2
- SYT16 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 297/622 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.835); catalogued as rs763887935, COSV70857129; called by muse, mutect2, varscan2
- TAF1L | c.4186C>T p.R1396C | Missense Mutation (SNP) | VAF 197/358 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs535208015, COSV54265096; called by muse, mutect2, varscan2
- TBC1D31 | c.1225G>A p.G409R | Missense Mutation (SNP) | VAF 151/254 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.345); catalogued as rs544995570; called by muse, mutect2, varscan2
- THSD7B | c.2378C>T p.S793F | Missense Mutation (SNP) | VAF 130/334 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as rs1347902701, COSV55656405; called by muse, mutect2, varscan2
- TRANK1 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 178/469 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.033); catalogued as rs765493342, COSV100082538; called by muse, mutect2, varscan2
- TRBV29-1 | c.287G>A p.S96N | Missense Mutation (SNP) | VAF 284/610 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs1364028234; called by muse, mutect2, varscan2
- TRIM49 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 98/166 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as COSV100315860; called by muse, mutect2, varscan2
- TSHR | c.2062G>A p.D688N | Missense Mutation (SNP) | VAF 345/689 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53324994; called by muse, mutect2, varscan2
- TTN | c.85547G>A p.G28516E (on ENST00000591111; = p.G21092E on NM_003319.4) | Missense Mutation (SNP) | VAF 218/466 reads (47%) | PolyPhen probably damaging (1); catalogued as COSV59876098; called by muse, mutect2, varscan2
- TTN | c.21452C>T p.S7151L (on ENST00000591111; = p.S6224L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 211/443 reads (48%) | PolyPhen benign (0.244); catalogued as COSV60340266; called by muse, mutect2, varscan2
- UNC5A | c.1094C>T p.T365I | Missense Mutation (SNP) | VAF 358/358 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV56170914; called by muse, mutect2, varscan2
- VWA5B2 | c.2261G>A p.R754Q | Missense Mutation (SNP) | VAF 452/837 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs924770798, COSV56612430; called by muse, mutect2, varscan2
- WDR87 | c.4660G>A p.G1554R | Missense Mutation (SNP) | VAF 214/471 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV58207001; called by muse, mutect2, varscan2
- WWP2 | c.1312C>T p.Q438* | Nonsense Mutation (SNP) | VAF 177/397 reads (45%) | catalogued as COSV100598539; called by muse, mutect2
- ZBBX | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 71/227 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.311); catalogued as COSV100284954; called by muse, mutect2, varscan2
- ZEB2 | c.3392C>T p.P1131L | Missense Mutation (SNP) | VAF 309/643 reads (48%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV57963067; called by muse, mutect2, varscan2
- ZFP64 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 205/433 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99402042; called by muse, mutect2, varscan2
- ZNF662 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 181/400 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV60241093; called by muse, mutect2, varscan2
- ZNF722P | c.866G>A p.R289K | Missense Mutation (SNP) | VAF 156/382 reads (41%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.492); catalogued as COSV57427615; called by muse, mutect2, varscan2
- ZSWIM5 | c.3079C>T p.L1027F | Missense Mutation (SNP) | VAF 365/573 reads (64%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.465); catalogued as COSV99870397; called by muse, mutect2, varscan2
- ABCG8 | c.1101T>A p.D367E | Missense Mutation (SNP) | VAF 203/509 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACADL | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 153/354 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ACAN | c.1916C>T p.P639L | Missense Mutation (SNP) | VAF 472/797 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ACIN1 | c.2249A>G p.E750G | Missense Mutation (SNP) | VAF 162/398 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ADAMTS7 | c.2359G>A p.E787K | Missense Mutation (SNP) | VAF 123/359 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- ADCY10 | c.4672G>A p.E1558K | Missense Mutation (SNP) | VAF 74/247 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADCY5 | c.2261C>T p.S754F | Missense Mutation (SNP) | VAF 151/364 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ADGRB2 | c.3372G>A p.W1124* | Nonsense Mutation (SNP) | VAF 305/469 reads (65%) | called by muse, mutect2, varscan2
- ALDH1A1 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 53/207 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ANGPT4 | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 142/383 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, varscan2
- ANK3 | c.3292G>A p.E1098K (on ENST00000280772 / NM_001320874.2; = p.E232K on NM_001149.3) | Missense Mutation (SNP) | VAF 115/272 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- ANKFN1 | c.3632C>T p.P1211L (on ENST00000653862; = p.P1064L on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 415/416 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- AQP9 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 96/250 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASF1B | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 215/523 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ATP1A4 | c.1907G>T p.G636V | Missense Mutation (SNP) | VAF 125/459 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- BCL6B | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 353/353 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRWD3 | c.4481C>T p.P1494L | Missense Mutation (SNP) | VAF 161/161 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- CACNA1C | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 193/301 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CACNB2 | c.1942G>A p.E648K (on ENST00000324631 / NM_201596.3; = p.E593K on NM_000724.4) | Missense Mutation (SNP) | VAF 113/228 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- CAD | c.4714G>C p.V1572L | Missense Mutation (SNP) | VAF 32/550 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2
- CCSER1 | c.2019G>A p.M673I | Missense Mutation (SNP) | VAF 130/254 reads (51%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CD109 | c.2432C>T p.P811L | Missense Mutation (SNP) | VAF 135/320 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- CDC42BPA | c.4092G>A p.W1364* (on ENST00000334218 / NM_001366019.2; = p.W1351* on NM_003607.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 126/334 reads (38%) | called by muse, mutect2, varscan2
- CFAP54 | c.9043G>A p.E3015K | Missense Mutation (SNP) | VAF 137/244 reads (56%) | SIFT tolerated (0.64); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- CHGB | c.914G>A p.G305E | Missense Mutation (SNP) | VAF 332/332 reads (100%) | SIFT tolerated (0.77); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CHRFAM7A | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 25/126 reads (20%) | called by muse, mutect2, varscan2
- CLIP1 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 129/525 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CNTN5 | c.596G>C p.G199A | Missense Mutation (SNP) | VAF 125/324 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- CNTNAP5 | c.1781A>G p.Y594C | Missense Mutation (SNP) | VAF 56/454 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- COG4 | c.1640C>T p.S547F | Missense Mutation (SNP) | VAF 170/347 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COPE | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 277/590 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- CREB1 | c.608del p.G203Afs*5 (on ENST00000432329 / NM_134442.5; = p.G189Afs*5 on NM_004379.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 236/473 reads (50%) | called by mutect2, pindel*, varscan2
- CSMD3 | c.1163A>T p.H388L | Missense Mutation (SNP) | VAF 86/895 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- CT45A3 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP2C18 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 130/247 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- CYP2C8 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 125/301 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- CYP4F3 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 129/278 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- DACT1 | c.2018G>A p.R673Q | Missense Mutation (SNP) | VAF 452/975 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DACT2 | c.2187G>A p.W729* | Nonsense Mutation (SNP) | VAF 258/612 reads (42%) | called by muse, mutect2, varscan2
- DLGAP1 | c.869A>G p.E290G | Missense Mutation (SNP) | VAF 360/361 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, varscan2
- DNAH7 | c.2260C>T p.P754S | Missense Mutation (SNP) | VAF 169/394 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNM1 | c.1648C>A p.L550M | Missense Mutation (SNP) | VAF 77/278 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- EGFR | c.782A>G p.K261R | Missense Mutation (SNP) | VAF 380/844 reads (45%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- EIF2S1 | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 160/400 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- ELAPOR2 | c.1390G>A p.G464R (on ENST00000450689 / NM_001142749.3; = p.G297R on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 104/249 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- EML6 | c.2992G>A p.E998K | Missense Mutation (SNP) | VAF 224/458 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- EOGT | c.508C>T p.H170Y | Missense Mutation (SNP) | VAF 125/308 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- EYS | c.1941C>A p.C647* | Nonsense Mutation (SNP) | VAF 171/396 reads (43%) | called by muse, mutect2, varscan2
- FAM83C | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 339/732 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM83E | c.905T>A p.I302K | Missense Mutation (SNP) | VAF 588/1016 reads (58%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2
- FAM90A26 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 120/120 reads (100%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- FCHO1 | c.195-1G>A p.X65_splice | Splice Site (SNP) | VAF 190/348 reads (55%) | called by muse, mutect2, varscan2
- FGB | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 96/256 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGGY | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 213/343 reads (62%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- FILIP1L | c.2339G>A p.S780N (on ENST00000354552 / NM_182909.3; = p.S540N on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 247/581 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FLG2 | c.2108C>T p.S703L | Missense Mutation (SNP) | VAF 84/270 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- FOXA2 | c.227C>T p.S76F (on ENST00000377115 / NM_153675.3; = p.S82F on NM_021784.5) | Missense Mutation (SNP) | VAF 573/864 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- FREM3 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 211/574 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- GJA10 | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 210/472 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- GOLGA6C | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 37/343 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- GPR158 | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 222/509 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- GPR27 | c.1026C>G p.N342K | Missense Mutation (SNP) | VAF 496/942 reads (53%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GPR45 | c.10A>C p.N4H | Missense Mutation (SNP) | VAF 164/370 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- GTF3C1 | c.2537C>T p.S846F | Missense Mutation (SNP) | VAF 353/699 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- IGDCC4 | c.1889C>T p.P630L | Missense Mutation (SNP) | VAF 168/446 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- IL27RA | c.1675C>T p.P559S | Missense Mutation (SNP) | VAF 246/609 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.074); called by muse, mutect2
- INPP5J | c.1967C>T p.P656L (on ENST00000331075 / NM_001284285.2; = p.P288L on NM_001002837.2) | Missense Mutation (SNP) | VAF 239/507 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGA6 | c.2110G>C p.V704L (on ENST00000442250; = p.V665L on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 140/428 reads (33%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.644); called by muse, mutect2
- ITPKA | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 361/940 reads (38%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IVL | c.1493G>A p.G498E | Missense Mutation (SNP) | VAF 392/657 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- JCAD | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 265/506 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- KAT6A | c.3535A>T p.I1179F | Missense Mutation (SNP) | VAF 356/357 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KAT8 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 263/540 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA0319 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 180/365 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- KPNA6 | c.1198del p.W400Gfs*31 | Frame Shift Del (DEL) | VAF 104/412 reads (25%) | called by mutect2, pindel*, varscan2
- KRT2 | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 264/264 reads (100%) | called by muse, mutect2, varscan2
- KRTAP12-3 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 234/524 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- L1CAM | c.3484G>A p.D1162N | Missense Mutation (SNP) | VAF 364/366 reads (99%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- LAMA2 | c.8144T>A p.L2715H | Missense Mutation (SNP) | VAF 203/447 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LAMB3 | c.467C>T p.T156I | Missense Mutation (SNP) | VAF 459/725 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- LIFR | c.738G>A p.W246* | Nonsense Mutation (SNP) | VAF 148/148 reads (100%) | called by muse, mutect2, varscan2
- LIMCH1 | c.916G>A p.G306S | Missense Mutation (SNP) | VAF 172/297 reads (58%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- LIMCH1 | c.917G>A p.G306D | Missense Mutation (SNP) | VAF 169/295 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- LRRC53 | c.1714C>A p.L572I | Missense Mutation (SNP) | VAF 101/382 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- LRRC53 | c.737T>G p.L246R | Missense Mutation (SNP) | VAF 113/410 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- LRRD1 | c.1995_2006del p.E665_N669delinsD | In Frame Del (DEL) | VAF 82/272 reads (30%) | called by mutect2, pindel, varscan2
- MALRD1 | c.5099C>T p.S1700F | Missense Mutation (SNP) | VAF 66/196 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- MAN2A2 | c.2027T>C p.L676P | Missense Mutation (SNP) | VAF 241/639 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MAP3K21 | c.1796A>T p.Q599L | Missense Mutation (SNP) | VAF 188/301 reads (62%) | SIFT tolerated (0.62); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MEGF8 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 319/683 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MGAM2 | c.2779A>C p.S927R | Missense Mutation (SNP) | VAF 229/509 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- MICB | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 112/350 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); called by muse, mutect2
- MMP2 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 169/439 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- MOG | c.90G>A p.G30= | Splice Region (SNP) | VAF 180/361 reads (50%) | called by muse, mutect2, varscan2
- MRGPRX1 | c.473G>A p.W158* | Nonsense Mutation (SNP) | VAF 182/446 reads (41%) | called by muse, mutect2, varscan2
- MTSS1 | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 93/791 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- MUC16 | c.38065C>T p.P12689S | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MXRA5 | c.3185A>C p.E1062A | Missense Mutation (SNP) | VAF 282/282 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NARS2 | c.1285C>T p.Q429* | Nonsense Mutation (SNP) | VAF 105/211 reads (50%) | called by muse, mutect2, varscan2
- NAXD | c.86_89del p.P29Hfs*6 | Frame Shift Del (DEL) | VAF 318/548 reads (58%) | called by mutect2, pindel, varscan2
- NCF2 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 322/499 reads (65%) | SIFT tolerated (0.49); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NCF4 | c.835C>T p.Q279* | Nonsense Mutation (SNP) | VAF 180/438 reads (41%) | called by muse, mutect2, varscan2
- NEB | c.9638G>A p.W3213* | Nonsense Mutation (SNP) | VAF 103/300 reads (34%) | called by muse, mutect2, varscan2
- NECAB1 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 119/493 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- NMI | c.764G>A p.R255K | Missense Mutation (SNP) | VAF 122/296 reads (41%) | SIFT tolerated (0.72); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- NR4A3 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 412/596 reads (69%) | SIFT tolerated (0.34); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ONECUT1 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 622/1016 reads (61%) | SIFT deleterious (0.05); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- OR11H2 | c.929G>A p.G310E (on ENST00000556246; = p.G321E on NM_001197287.1) | Missense Mutation (SNP) | VAF 82/500 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- OR4K14 | c.667C>T p.L223F | Missense Mutation (SNP) | VAF 253/539 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- OR5T2 | c.869A>T p.Y290F | Missense Mutation (SNP) | VAF 220/387 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- OTOG | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 202/549 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- OTOL1 | c.558G>T p.L186F | Missense Mutation (SNP) | VAF 188/378 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- PACRGL | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 110/301 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PCSK6 | c.1693G>A p.G565R | Missense Mutation (SNP) | VAF 162/442 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PHC3 | c.334C>T p.P112S (on ENST00000494943 / NM_001308116.2; = p.P124S on NM_024947.4) | Missense Mutation (SNP) | VAF 226/468 reads (48%) | SIFT tolerated (0.89); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PIK3C2G | c.3956G>A p.R1319K (on ENST00000676171; = p.R1278K on NM_004570.5) | Missense Mutation (SNP) | VAF 73/304 reads (24%) | SIFT tolerated (0.9); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PITPNM3 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 186/186 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PLEC | c.9143C>T p.S3048F (on ENST00000322810 / NM_201380.4; = p.S2938F on NM_000445.5) | Missense Mutation (SNP) | VAF 42/1306 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); called by muse, mutect2
- PLXNA4 | c.3088C>T p.Q1030* | Nonsense Mutation (SNP) | VAF 307/663 reads (46%) | called by muse, mutect2, varscan2
- PPP1R9A | c.3092G>A p.G1031E | Missense Mutation (SNP) | VAF 130/309 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PPP1R9A | c.3094A>T p.M1032L | Missense Mutation (SNP) | VAF 130/312 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- PPP4R3C | c.55T>C p.W19R | Missense Mutation (SNP) | VAF 169/169 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- PRB3 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 197/412 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, varscan2
- PRB3 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 82/368 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.948); called by muse, varscan2
- PREX2 | c.4816G>A p.E1606K | Missense Mutation (SNP) | VAF 169/673 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- PROM2 | c.1348G>A p.G450S | Missense Mutation (SNP) | VAF 382/768 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- RBP3 | c.1361G>A p.G454D | Missense Mutation (SNP) | VAF 203/451 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- RFPL1 | c.648G>A p.W216* | Nonsense Mutation (SNP) | VAF 295/642 reads (46%) | called by muse, mutect2, varscan2
- ROS1 | c.3587G>A p.G1196E | Missense Mutation (SNP) | VAF 157/400 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- RSPH3 | c.1462G>A p.G488S (on ENST00000252655; = p.G346S on NM_031924.8) | Missense Mutation (SNP) | VAF 181/375 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SALL1 | c.1999T>G p.S667A | Missense Mutation (SNP) | VAF 48/759 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.192); called by muse, mutect2
- SBF1 | c.4571C>T p.P1524L | Missense Mutation (SNP) | VAF 214/420 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SDC1 | c.497C>T p.T166I | Missense Mutation (SNP) | VAF 323/729 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SIK3 | c.953C>T p.P318L (on ENST00000445177 / NM_001366686.2; = p.P324L on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 154/317 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SIN3A | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 221/401 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SLC12A5 | c.2842G>A p.E948K (on ENST00000454036 / NM_001134771.2; = p.E925K on NM_020708.5) | Missense Mutation (SNP) | VAF 18/536 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.21); called by muse, mutect2
- SLC17A4 | c.1289G>A p.G430E | Missense Mutation (SNP) | VAF 85/212 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC17A6 | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 84/261 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SLC23A1 | c.983C>T p.T328I | Missense Mutation (SNP) | VAF 405/406 reads (100%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- SLFN14 | c.2086C>T p.H696Y | Missense Mutation (SNP) | VAF 229/229 reads (100%) | SIFT tolerated (0.83); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SMG1 | c.2033T>C p.F678S | Missense Mutation (SNP) | VAF 132/291 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SNX6 | c.698A>T p.H233L (on ENST00000652385; = p.H105L on NM_021249.5) | Missense Mutation (SNP) | VAF 78/228 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPECC1L | c.2294C>A p.S765Y | Missense Mutation (SNP) | VAF 279/587 reads (48%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- SPNS1 | c.184G>C p.V62L | Missense Mutation (SNP) | VAF 430/835 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- ST18 | c.1363T>A p.S455T | Missense Mutation (SNP) | VAF 383/584 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- STMN2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 278/1012 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- SYNJ2 | c.3196C>T p.P1066S | Missense Mutation (SNP) | VAF 142/302 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- TACR1 | c.613T>A p.Y205N | Missense Mutation (SNP) | VAF 205/436 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEDDM1 | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 192/592 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TGM7 | c.432G>A p.W144* | Nonsense Mutation (SNP) | VAF 111/192 reads (58%) | called by muse, mutect2, varscan2
- THRA | c.668C>T p.T223I | Missense Mutation (SNP) | VAF 255/255 reads (100%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TM9SF2 | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TM9SF4 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 312/758 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.058); called by muse, mutect2
- TMEM161A | c.437T>C p.F146S | Missense Mutation (SNP) | VAF 179/400 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- TMEM74 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 249/864 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- TOGARAM2 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 474/1150 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRANK1 | c.3292G>A p.E1098K | Missense Mutation (SNP) | VAF 383/746 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPM6 | c.2199G>A p.W733* | Nonsense Mutation (SNP) | VAF 94/244 reads (39%) | called by muse, mutect2, varscan2
- TTN | c.21827T>G p.V7276G (on ENST00000591111; = p.V6349G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 186/422 reads (44%) | PolyPhen benign (0.306); called by muse, mutect2, varscan2
- USP19 | c.1663C>T p.R555W | Missense Mutation (SNP) | VAF 434/838 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP29 | c.1997G>A p.G666E | Missense Mutation (SNP) | VAF 224/488 reads (46%) | SIFT tolerated (0.84); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- VCX | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 86/138 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.048); called by mutect2, varscan2
- VCX2 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- VCX3B | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 60/64 reads (94%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.632); called by mutect2, varscan2
- XIRP1 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 372/707 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZCCHC2 | c.3103C>T p.P1035S | Missense Mutation (SNP) | VAF 275/276 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ZNF652 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 222/222 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ZNF722P | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 129/299 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ABCC4 | c.2158C>T p.L720= | Silent (SNP) | VAF 89/309 reads (29%) | catalogued as rs910107842, COSV65317965; called by muse, mutect2, varscan2
- ABI3BP | c.1276C>T p.L426= | Silent (SNP) | VAF 115/321 reads (36%) | called by muse, mutect2, varscan2
- ABL1 | c.2451C>T p.P817= | Silent (SNP) | VAF 267/731 reads (37%) | catalogued as rs1344752150; called by muse, mutect2, varscan2
- ACIN1 | c.1500C>T p.V500= | Silent (SNP) | VAF 291/593 reads (49%) | called by muse, mutect2, varscan2
- ADAMTS18 | c.2640C>T p.I880= | Silent (SNP) | VAF 183/461 reads (40%) | catalogued as rs148705153, COSV51422871; called by muse, mutect2, varscan2
- ADAMTS7 | c.2358G>A p.K786= | Silent (SNP) | VAF 123/362 reads (34%) | catalogued as rs927716529; called by muse, mutect2, varscan2
- AGRN | c.765C>T p.F255= | Silent (SNP) | VAF 504/1006 reads (50%) | called by muse, mutect2, varscan2
- ANKH | c.1314G>A p.V438= | Silent (SNP) | VAF 239/239 reads (100%) | called by muse, mutect2, varscan2
- APOB | c.759G>A p.R253= | Silent (SNP) | VAF 254/541 reads (47%) | catalogued as COSV51932161; called by muse, mutect2, varscan2
- ARIH2 | c.1047C>T p.I349= | Silent (SNP) | VAF 242/502 reads (48%) | catalogued as rs781636704, COSV100711350; called by muse, varscan2
- ASCC3 | c.4158T>G p.R1386= | Silent (SNP) | VAF 72/186 reads (39%) | called by muse, mutect2, varscan2
- ASF1B | c.579C>T p.L193= | Silent (SNP) | VAF 217/525 reads (41%) | catalogued as COSV54616743; called by muse, mutect2, varscan2
- BCL6B | c.1233C>T p.P411= | Silent (SNP) | VAF 352/352 reads (100%) | called by muse, mutect2, varscan2
- C14orf132 | c.255C>T p.S85= (on ENST00000553782 / NM_001289139.2; = p.S54= on NM_001252507.3) | Silent (SNP) | VAF 272/566 reads (48%) | called by muse, varscan2
- CCDC61 | c.1170C>T p.P390= | Silent (SNP) | VAF 528/1176 reads (45%) | called by muse, mutect2
- CCR1 | c.738C>T p.I246= | Silent (SNP) | VAF 110/264 reads (42%) | catalogued as rs951216689, COSV56122082; called by muse, mutect2, varscan2
- CD1A | c.870C>T p.I290= | Silent (SNP) | VAF 87/256 reads (34%) | catalogued as rs757980794, COSV56863635, COSV99192270; called by muse, mutect2, varscan2
- CD207 | c.318C>T p.G106= | Silent (SNP) | VAF 37/654 reads (6%) | catalogued as rs371446596; called by muse, mutect2
- CDK9 | c.747C>T p.T249= | Silent (SNP) | VAF 160/442 reads (36%) | catalogued as rs1326186686; called by muse, mutect2, varscan2
- CFH | c.2715C>T p.F905= | Silent (SNP) | VAF 202/314 reads (64%) | catalogued as COSV66410627; called by muse, mutect2, varscan2
- CHAT | c.1407C>T p.I469= | Silent (SNP) | VAF 151/323 reads (47%) | called by muse, mutect2, varscan2
- CHL1 | c.579G>A p.V193= | Silent (SNP) | VAF 206/496 reads (42%) | called by muse, mutect2, varscan2
- CLPTM1 | c.1830C>G p.P610= | Silent (SNP) | VAF 428/910 reads (47%) | catalogued as COSV61611521; called by muse, mutect2, varscan2
- COG2 | c.1213C>T p.L405= | Silent (SNP) | VAF 53/245 reads (22%) | called by muse, mutect2, varscan2
- COL4A4 | c.1146G>A p.G382= | Silent (SNP) | VAF 142/333 reads (43%) | called by muse, mutect2, varscan2
- CSF2RB | c.1461C>T p.F487= | Silent (SNP) | VAF 184/470 reads (39%) | catalogued as COSV53256967, COSV99453961; called by muse, mutect2, varscan2
- DCHS2 | c.1368G>A p.G456= | Silent (SNP) | VAF 296/508 reads (58%) | catalogued as rs1239481129; called by muse, mutect2, varscan2
- DNAH7 | c.2865C>T p.F955= | Silent (SNP) | VAF 138/299 reads (46%) | catalogued as rs1196961789, COSV56785813; called by muse, mutect2, varscan2
- DNAH7 | c.813G>A p.L271= | Silent (SNP) | VAF 167/371 reads (45%) | catalogued as COSV56775091; called by muse, mutect2, varscan2
- DNMBP | c.2907G>A p.R969= | Silent (SNP) | VAF 102/218 reads (47%) | called by muse, mutect2, varscan2
- DYRK4 | c.585G>A p.K195= | Silent (SNP) | VAF 170/261 reads (65%) | called by muse, mutect2, varscan2
- EBF3 | c.1680G>A p.K560= (on ENST00000355311 / NM_001375392.1; = p.K515= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 223/522 reads (43%) | called by muse, mutect2, varscan2
- ENPP7 | c.795C>T p.F265= | Silent (SNP) | VAF 380/380 reads (100%) | called by muse, mutect2, varscan2
- EPHA6 | c.2796C>T p.I932= | Silent (SNP) | VAF 194/375 reads (52%) | called by muse, mutect2, varscan2
- ERVV-2 | c.816G>A p.K272= | Silent (SNP) | VAF 321/710 reads (45%) | called by muse, mutect2, varscan2
- ESRP1 | c.555G>A p.G185= | Silent (SNP) | VAF 166/300 reads (55%) | catalogued as rs759328702; called by muse, mutect2, varscan2
- FNDC10 | c.375C>T p.L125= | Silent (SNP) | VAF 645/1299 reads (50%) | catalogued as rs1042937869; called by muse, mutect2, varscan2
- FPR3 | c.123C>T p.V41= | Silent (SNP) | VAF 249/520 reads (48%) | catalogued as COSV59329932; called by muse, mutect2, varscan2
- FRG2C | c.108G>A p.E36= | Silent (SNP) | VAF 115/1296 reads (9%) | called by muse, mutect2
- GAK | c.1995C>T p.F665= | Silent (SNP) | VAF 228/378 reads (60%) | called by muse, mutect2, varscan2
- GCNT1 | c.261G>A p.R87= | Silent (SNP) | VAF 205/301 reads (68%) | catalogued as rs779553603; called by muse, mutect2, varscan2
- GDF3 | c.135A>G p.Q45= | Silent (SNP) | VAF 303/464 reads (65%) | called by muse, mutect2, varscan2
- GOLGA8A | c.1761C>T p.S587= (on ENST00000432566; = p.S559= on NM_181077.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 154/837 reads (18%) | catalogued as rs752104883; called by muse, mutect2, varscan2
- GRM7 | c.1545C>T p.V515= | Silent (SNP) | VAF 136/388 reads (35%) | catalogued as COSV63144025; called by muse, mutect2
- HEATR5B | c.1080C>T p.I360= | Silent (SNP) | VAF 168/366 reads (46%) | catalogued as rs767346833, COSV99249870; called by muse, mutect2, varscan2
- HHIPL1 | c.481C>T p.L161= | Silent (SNP) | VAF 292/626 reads (47%) | called by muse, mutect2, varscan2
- HS3ST2 | c.963C>G p.L321= | Silent (SNP) | VAF 281/666 reads (42%) | catalogued as rs539271647, COSV54467207; called by muse, mutect2, varscan2
- IRAG2 | c.1200C>T p.R400= | Silent (SNP) | VAF 87/304 reads (29%) | called by muse, mutect2, varscan2
- KCNQ5 | c.1917C>T p.L639= | Silent (SNP) | VAF 190/395 reads (48%) | catalogued as rs1272954086, COSV59660807; called by muse, mutect2, varscan2
- KIR3DL1 | c.1218C>T p.F406= | Silent (SNP) | VAF 231/493 reads (47%) | catalogued as COSV58490079; called by muse, mutect2
- KLHL32 | c.1041C>T p.F347= | Silent (SNP) | VAF 168/428 reads (39%) | called by muse, mutect2, varscan2
- LAMB3 | c.468C>T p.T156= | Silent (SNP) | VAF 462/726 reads (64%) | called by muse, mutect2, varscan2
- LDB1 | c.69C>T p.P23= | Silent (SNP) | VAF 174/374 reads (47%) | catalogued as COSV100756394; called by muse, mutect2, varscan2
- LMOD2 | c.261G>A p.G87= | Silent (SNP) | VAF 200/402 reads (50%) | catalogued as rs777407621; called by muse, mutect2
- LNPK | c.163C>T p.L55= | Silent (SNP) | VAF 166/381 reads (44%) | called by muse, mutect2, varscan2
- MAP3K21 | c.1323C>T p.S441= | Silent (SNP) | VAF 151/431 reads (35%) | called by muse, mutect2, varscan2
- MAP7 | c.483G>A p.S161= | Silent (SNP) | VAF 120/282 reads (43%) | catalogued as rs776519403, COSV63421661; called by muse, mutect2, varscan2
- MAPK8IP2 | c.2196G>T p.R732= | Silent (SNP) | VAF 310/708 reads (44%) | called by muse, mutect2
- MED19 | c.352C>T p.L118= | Silent (SNP) | VAF 180/478 reads (38%) | called by muse, varscan2
- MED23 | c.3369G>T p.G1123= | Silent (SNP) | VAF 148/325 reads (46%) | called by muse, mutect2, varscan2
- MFNG | c.765C>T p.S255= | Silent (SNP) | VAF 326/682 reads (48%) | called by muse, mutect2, varscan2
- MSTN | c.1098G>A p.A366= | Silent (SNP) | VAF 110/241 reads (46%) | catalogued as rs768820223, COSV53620743, COSV99640469; called by muse, mutect2, varscan2
- MYOF | c.2523C>T p.G841= | Silent (SNP) | VAF 126/340 reads (37%) | catalogued as rs530491139; called by muse, mutect2, varscan2
- NBPF6 | c.1983G>A p.R661= | Silent (SNP) | VAF 70/141 reads (50%) | catalogued as rs368090196; called by muse, mutect2, varscan2
- NCBP1 | c.2298G>A p.E766= | Silent (SNP) | VAF 160/280 reads (57%) | called by muse, mutect2, varscan2
- NCF2 | c.99G>A p.Q33= | Silent (SNP) | VAF 322/496 reads (65%) | catalogued as rs1558109147; called by muse, mutect2, varscan2
- NDNF | c.72C>T p.T24= | Silent (SNP) | VAF 184/440 reads (42%) | called by muse, mutect2, varscan2
- NKAIN1 | c.270C>T p.S90= | Silent (SNP) | VAF 106/333 reads (32%) | called by muse, mutect2, varscan2
- NLRX1 | c.168G>C p.S56= | Silent (SNP) | VAF 251/412 reads (61%) | catalogued as COSV52711154; called by muse, mutect2, varscan2
- NPAP1 | c.1776C>T p.S592= | Silent (SNP) | VAF 251/408 reads (62%) | catalogued as rs1363117389, COSV61508770; called by muse, mutect2, varscan2
- NSUN7 | c.1380G>A p.G460= | Silent (SNP) | VAF 81/197 reads (41%) | catalogued as rs1313237521; called by muse, mutect2, varscan2
- NWD2 | c.783G>A p.R261= | Silent (SNP) | VAF 145/418 reads (35%) | called by muse, mutect2, varscan2
- OLFM1 | c.1410C>T p.I470= (on ENST00000371793 / NM_001282611.2; = p.I452= on NM_014279.5) | Silent (SNP) | VAF 208/345 reads (60%) | catalogued as rs1163555806; called by muse, mutect2, varscan2
- OR2M5 | c.405C>T p.L135= | Silent (SNP) | VAF 137/236 reads (58%) | called by muse, mutect2, varscan2
- OR4K2 | c.903G>A p.L301= | Silent (SNP) | VAF 64/453 reads (14%) | catalogued as rs540643299, COSV100064819, COSV53851107; called by muse, mutect2, varscan2
- OR4N2 | c.531C>T p.F177= | Silent (SNP) | VAF 192/1378 reads (14%) | called by muse, mutect2, varscan2
- OR5P2 | c.522C>T p.F174= | Silent (SNP) | VAF 244/445 reads (55%) | catalogued as COSV61490922; called by muse, mutect2, varscan2
- OR9I1 | c.912C>T p.V304= | Silent (SNP) | VAF 125/317 reads (39%) | catalogued as rs368868026, COSV56925654, COSV56925909; called by muse, mutect2, varscan2
- PAPLN | c.783G>A p.G261= (on ENST00000554301; = p.G234= on NM_173462.4) | Silent (SNP) | VAF 442/890 reads (50%) | called by muse, mutect2, varscan2
- PATZ1 | c.609C>T p.A203= | Silent (SNP) | VAF 553/1058 reads (52%) | catalogued as rs758682147, COSV53229122; called by muse, mutect2, varscan2
- PHF21A | c.1149C>T p.I383= (on ENST00000418153 / NM_001101802.3; = p.I384= on NM_016621.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 190/334 reads (57%) | called by muse, mutect2, varscan2
- PITPNM3 | c.1800C>T p.I600= | Silent (SNP) | VAF 265/266 reads (100%) | catalogued as rs896271208; called by muse, mutect2, varscan2
- POLI | c.1560C>T p.L520= | Silent (SNP) | VAF 155/155 reads (100%) | catalogued as COSV99470852; called by muse, mutect2, varscan2
- PPFIA4 | c.1560C>T p.S520= (on ENST00000447715; = p.S495= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 182/670 reads (27%) | catalogued as rs1008193144; called by muse, mutect2, varscan2
- PPP1R32 | c.474G>A p.Q158= | Silent (SNP) | VAF 191/530 reads (36%) | called by muse, mutect2, varscan2
- PTPN14 | c.1302C>T p.I434= | Silent (SNP) | VAF 196/589 reads (33%) | called by muse, mutect2, varscan2
- PXDNL | c.3093G>A p.R1031= | Silent (SNP) | VAF 300/956 reads (31%) | catalogued as COSV62492989; called by muse, mutect2, varscan2
- PXMP4 | c.555C>T p.S185= | Silent (SNP) | VAF 334/736 reads (45%) | catalogued as rs767911987; called by muse, mutect2, varscan2
- QSER1 | c.2094A>C p.I698= (on ENST00000399302; = p.I827= on NM_001076786.3) | Silent (SNP) | VAF 185/306 reads (60%) | called by muse, mutect2, varscan2
- RBM14 | c.1722G>A p.P574= | Silent (SNP) | VAF 300/783 reads (38%) | catalogued as rs748248316, COSV59557976; called by muse, mutect2, varscan2
- ROBO2 | c.285C>T p.I95= | Silent (SNP) | VAF 263/580 reads (45%) | catalogued as rs757943328, COSV59913772; called by muse, mutect2, varscan2
- RYR1 | c.12249C>T p.P4083= | Silent (SNP) | VAF 153/349 reads (44%) | catalogued as COSV100615464, COSV62113779; called by muse, mutect2, varscan2
- SERPINA1 | c.66C>A p.S22= | Silent (SNP) | VAF 25/908 reads (3%) | called by muse, mutect2
- SHANK2 | c.1203C>T p.S401= | Silent (SNP) | VAF 317/579 reads (55%) | catalogued as rs782200396; called by muse, mutect2, varscan2
- SHCBP1 | c.1029C>T p.L343= | Silent (SNP) | VAF 259/569 reads (46%) | catalogued as rs1351587001; called by muse, mutect2, varscan2
- SLC22A10 | c.1137C>T p.F379= | Silent (SNP) | VAF 197/419 reads (47%) | catalogued as rs564171817, COSV60419818; called by muse, mutect2, varscan2
- SLC22A8 | c.741C>T p.F247= | Silent (SNP) | VAF 165/415 reads (40%) | catalogued as rs888010597, COSV60327132; called by muse, mutect2, varscan2
- SLC37A1 | c.88C>T p.L30= | Silent (SNP) | VAF 154/395 reads (39%) | called by muse, mutect2, varscan2
- SLC5A5 | c.1731G>A p.K577= | Silent (SNP) | VAF 237/531 reads (45%) | catalogued as rs760244527, COSV55833108; called by muse, mutect2, varscan2
- SLC7A10 | c.1269C>T p.N423= | Silent (SNP) | VAF 169/342 reads (49%) | called by muse, mutect2, varscan2
- SORL1 | c.6027G>A p.G2009= | Silent (SNP) | VAF 164/358 reads (46%) | catalogued as rs867962008; called by muse, mutect2, varscan2
- SPATA33 | c.252C>T p.V84= | Silent (SNP) | VAF 251/483 reads (52%) | catalogued as rs369973281; called by muse, mutect2, varscan2
- SPATC1L | c.666G>A p.T222= (on ENST00000291672 / NM_001142854.2; = p.T68= on NM_032261.5) | Silent (SNP) | VAF 374/825 reads (45%) | catalogued as rs771987900; called by muse, mutect2, varscan2
- SRL | c.966C>T p.I322= | Silent (SNP) | VAF 303/841 reads (36%) | catalogued as rs756763066, COSV68424642; called by muse, mutect2, varscan2
- STRIT1 | c.39G>A p.L13= | Silent (SNP) | VAF 154/350 reads (44%) | called by muse, mutect2, varscan2
- SYT17 | c.1263C>T p.F421= | Silent (SNP) | VAF 181/351 reads (52%) | called by muse, mutect2, varscan2
- TACC2 | c.4389C>T p.L1463= | Silent (SNP) | VAF 242/512 reads (47%) | catalogued as rs765884417; called by muse, mutect2, varscan2
- TALDO1 | c.39C>T p.S13= | Silent (SNP) | VAF 286/528 reads (54%) | catalogued as rs1338743503, COSV59797881, COSV59798420; called by muse, varscan2
- TC2N | c.1170C>T p.F390= | Silent (SNP) | VAF 138/297 reads (46%) | catalogued as rs776984565, COSV61746360, COSV61747345; called by muse, mutect2, varscan2
- TCF20 | c.2337T>G p.A779= | Silent (SNP) | VAF 433/913 reads (47%) | called by muse, mutect2, varscan2
- TM9SF4 | c.366C>T p.A122= | Silent (SNP) | VAF 310/748 reads (41%) | catalogued as rs751422835; called by muse, mutect2
- TMEM18 | c.321C>T p.I107= | Silent (SNP) | VAF 149/330 reads (45%) | called by muse, mutect2, varscan2
- TMUB2 | c.789A>G p.P263= (on ENST00000538716 / NM_001353177.2; = p.P243= on NM_024107.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 431/432 reads (100%) | called by muse, mutect2, varscan2
- TNXB | c.12768C>T p.L4256= (on ENST00000647633; = p.L4009= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 70/251 reads (28%) | called by muse, mutect2, varscan2
- TP53BP2 | c.2796C>T p.P932= (on ENST00000343537 / NM_001031685.3; = p.P803= on NM_005426.2) | Silent (SNP) | VAF 286/455 reads (63%) | called by muse, mutect2, varscan2
- TPO | c.1122C>T p.A374= | Silent (SNP) | VAF 664/1279 reads (52%) | called by muse, mutect2, varscan2
- TRIM68 | c.1245C>T p.S415= | Silent (SNP) | VAF 213/551 reads (39%) | called by muse, mutect2, varscan2
- TTC39A | c.828C>T p.V276= (on ENST00000447632 / NM_001297665.1; = p.V241= on NM_001080494.3) | Silent (SNP) | VAF 131/433 reads (30%) | catalogued as COSV52958032; called by muse, mutect2, varscan2
- USH2A | c.14907A>T p.G4969= | Silent (SNP) | VAF 300/472 reads (64%) | called by muse, mutect2, varscan2
- USP6 | c.810G>A p.R270= | Silent (SNP) | VAF 142/142 reads (100%) | called by muse, mutect2, varscan2
- XYLB | c.501C>T p.A167= | Silent (SNP) | VAF 341/638 reads (53%) | called by muse, mutect2, varscan2
- ZNF184 | c.1281C>T p.F427= | Silent (SNP) | VAF 207/379 reads (55%) | called by muse, mutect2, varscan2
- ZNF316 | c.1500C>T p.F500= | Silent (SNP) | VAF 417/814 reads (51%) | called by muse, mutect2, varscan2
- ZNF479 | c.279C>T p.F93= | Silent (SNP) | VAF 78/195 reads (40%) | catalogued as COSV100482628; called by muse, mutect2, varscan2
- ZNF536 | c.2700C>T p.I900= | Silent (SNP) | VAF 323/615 reads (53%) | catalogued as rs372913514, COSV62834521; called by muse, mutect2, varscan2
- ZNF554 | c.951C>T p.I317= | Silent (SNP) | VAF 263/592 reads (44%) | called by muse, mutect2, varscan2
- ZNF831 | c.3307C>T p.L1103= | Silent (SNP) | VAF 41/960 reads (4%) | catalogued as COSV100925869; called by muse, mutect2
- ZSCAN2 | c.1311G>A p.R437= | Silent (SNP) | VAF 239/649 reads (37%) | called by muse, mutect2, varscan2
- ABCC4 | c.2536-12845G>A | Intron (SNP) | VAF 169/289 reads (58%) | called by muse, mutect2, varscan2
- ANKRD31 | c.3424+1855C>T | Intron (SNP) | VAF 180/180 reads (100%) | catalogued as rs1186027556; called by muse, mutect2, varscan2
- ANO4 | c.-112A>T | 5'UTR (SNP) | VAF 303/465 reads (65%) | called by muse, mutect2, varscan2
- BNIP5 | c.*583A>C | 3'UTR (SNP) | VAF 153/357 reads (43%) | called by muse, mutect2, varscan2
- GNAS | c.2068+290G>A | Intron (SNP) | VAF 277/581 reads (48%) | called by muse, mutect2, varscan2
- KCNK17 | c.689-676G>A | Intron (SNP) | VAF 115/214 reads (54%) | catalogued as rs773120334; called by muse, mutect2, varscan2
- KCNK4 | c.*10C>G | 3'UTR (SNP) | VAF 381/985 reads (39%) | called by muse, mutect2, varscan2
- LCE1A | c.*50A>T | 3'UTR (SNP) | VAF 286/467 reads (61%) | called by muse, mutect2, varscan2
- LINC02767 | n.3800C>T | RNA (SNP) | VAF 259/409 reads (63%) | called by muse, mutect2, varscan2
- NPDC1 | c.113-206G>A | Intron (SNP) | VAF 244/405 reads (60%) | called by muse, mutect2, varscan2
- SYTL2 | c.1459+3099G>A | Intron (SNP) | VAF 138/248 reads (56%) | called by muse, mutect2, varscan2
- TAL1 | c.*2041T>G | 3'UTR (SNP) | VAF 178/544 reads (33%) | called by muse, mutect2, varscan2
